Gene-level copy-number profile of tumor specimen TCGA-G2-AA3B-01A from TCGA case TCGA-G2-AA3B, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.7 years (27,646 days).
Specimen TCGA-G2-AA3B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.716de860-5313-47d4-b394-9d7fa9db14ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-AA3B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/578b3556-1c20-48ea-8ec9-33aacc58c1c3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 615; copy number 3: 15,185; copy number 4: 10,204; copy number 5: 10,661; copy number 6: 12,916; copy number 7: 5,068; copy number 8: 1,364; copy number 9: 1,331; copy number 10: 1,206; copy number 11: 37; copy number 12: 132; copy number 13: 64; copy number 14: 173; copy number 15: 235; copy number 16: 129; copy number 17: 133; copy number 18: 208; copy number 19: 26; copy number 20: 14; copy number 21: 41; copy number 22: 15; copy number 30: 36; copy number 61: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-AA3B-01A-11D-A390-01): tumor purity 0.84, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 9,708 genes in 78 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–150,876,708, 278 genes, copy number 8 (broad region; genes not listed).
- chr1:156,249,224–167,708,696, 364 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:38,814–3,157,797, 49 genes, copy number 7: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1, AC018685.2, AC018685.3, AC011995.2, AC018685.1, AC011995.1, LINC01250, AC019118.2, AC019118.1.
- chr3:13,549,125–15,205,959, 36 genes, copy number 7: FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174, C3orf20, AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1, NR2C2, MRPS25, RBSN, AC090954.1, RPS3AP53, COL6A4P1.
- chr3:53,196,820–56,468,467, 37 genes, copy number 10–17: AC097015.1, TKT, DCP1A, Y_RNA, CACNA1D, SNORD38C, AC112218.1, AC092035.1, SNORD63, AC012467.1, CHDH, IL17RB, AC012467.2, ACTR8, SELENOK, AC115282.2, CABYRP1, AC115282.1, CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1, AC092059.1, LINC02017, LINC02030, AC121764.2, AC121764.3, WNT5A, WNT5A-AS1, AC121764.1, ERC2, AC025572.1, ERC2-IT1, MIR3938, RN7SKP45, RNA5SP133.
- chr3:89,587,886–119,818,485, 365 genes, copy number 7–8 (broad region; genes not listed).
- chr3:159,765,387–161,735,399, 36 genes, copy number 10–13: IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1.
- chr3:193,740,471–194,832,592, 40 genes, copy number 7: RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037, LINC02048, LINC00887, AC117469.1, CPN2, LRRC15, GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1, RNU6-1101P, RPL23AP93, TMEM44-AS1, TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2.
- chr4:10,486,395–20,037,972, 99 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr4:53,659,208–59,180,414, 102 genes, copy number 7–10 (broad region; genes not listed).
- chr4:68,509,441–69,526,014, 46 genes, copy number 7 (within-gene range 4–7): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1, AC093720.1, AC021146.8, UGT2B10, AC021146.9, AC021146.4, AC021146.11, AC021146.2, AC021146.3, AC021146.12, AC021146.6, AC021146.1, UGT2A3, AC021146.10, AC021146.5, AC021146.7, UGT2B27P, AC107401.1, UGT2B26P, UGT2B7, AC111000.2, AC111000.5, AC111000.3, AC111000.6, AC111000.1, AC111000.4, UGT2B11, AC114797.1, AC114786.1, UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P, AC108078.3, AC108078.2, UGT2B4, UGT2A3P7.
- chr4:76,886,029–79,877,770, 47 genes, copy number 7: AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4, ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3, PAQR3, RN7SL127P, LINC01088, NAA11, GK2, LINC00989, OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75.
- chr5:58,198–45,895,970, 710 genes, copy number 11–22 (broad region; genes not listed).
- chr6:29,636,060–31,180,731, 124 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr6:32,393,963–34,155,622, 93 genes, copy number 7 (broad region; genes not listed).
- chr6:39,299,001–46,954,943, 198 genes, copy number 7–14 (broad region; genes not listed).
- chr7:63,011,463–65,770,810, 137 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:76,650,401–97,872,542, 262 genes, copy number 7 (broad region; genes not listed).
- chr7:98,846,488–100,221,488, 71 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:37,421,341–145,066,685, 1,702 genes, copy number 9–14 (within-gene range 3–14) (broad region; genes not listed).
- chr9:136,647,872–137,615,360, 94 genes, copy number 8 (broad region; genes not listed).
- chr11:54,635,037–63,563,379, 452 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–6,124,770, 140 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr12:8,940,361–24,775,565, 326 genes, copy number 7 (broad region; genes not listed).
- chr12:30,755,167–41,574,745, 136 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr13:30,973,289–37,874,444, 95 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr13:73,191,528–114,337,626, 526 genes, copy number 7–9 (broad region; genes not listed).
- chr16:10,326,434–11,976,643, 65 genes, copy number 8 (broad region; genes not listed).
- chr16:18,781,295–20,158,391, 41 genes, copy number 7: RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, LINC02858, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B, GPR139, AC092132.2.
- chr17:26,989,189–32,053,504, 266 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:37,514,807–40,061,215, 102 genes, copy number 8–15 (within-gene range 4–15) (broad region; genes not listed).
- chr17:58,982,638–64,020,634, 175 genes, copy number 7–30 (within-gene range 5–30) (broad region; genes not listed).
- chr18:20,946,906–22,587,227, 41 genes, copy number 7: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18.
- chr18:23,598,926–25,953,468, 41 genes, copy number 7 (within-gene range 3–7): ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1.
- chr19:36,714,383–38,930,763, 96 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:646,615–3,039,076, 76 genes, copy number 7–10 (broad region; genes not listed).
- chr20:34,833,575–35,664,956, 36 genes, copy number 7 (within-gene range 6–7): HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1.
- chr20:49,794,811–51,023,107, 43 genes, copy number 7: RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1.
- chr21:10,328,411–46,665,124, 745 genes, copy number 7–8 (broad region; genes not listed).
- chr22:15,290,718–40,410,289, 1,067 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
